Gene-level copy-number profile of tumor specimen TCGA-AU-3779-01A from TCGA case TCGA-AU-3779, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.7 years (29,460 days).
Specimen TCGA-AU-3779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.8e5110ec-50de-4f35-81ff-d8bd3a687f4b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AU-3779-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c34c6961-73a2-4efa-9b3d-48fefe72297e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 3,306; copy number 2: 24,015; copy number 3: 23,932; copy number 4: 5,597; copy number 5: 1,447; copy number 6: 1,402; copy number 7: 23; copy number 8: 5; copy number 11: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AU-3779-01A-01D-1717-01): tumor purity 0.62, ploidy 2.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:54,151,606–55,146,645, 20 genes: MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,921 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–14,531,223, 224 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–57,837,046, 1,078 genes, copy number 5 (broad region; genes not listed).
- chr9:33,290,512–38,068,687, 204 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:37,936,707–37,936,768, 1 gene, copy number 6: RNU7-124P.
- chr19:30,850,975–40,950,660, 446 genes, copy number 6–11 (broad region; genes not listed).
- chr20:15,280,764–19,722,926, 80 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:25,407,673–25,624,014, 4 genes, copy number 8: GINS1, NINL, RNU6ATAC17P, NANP.
- chr20:25,654,595–25,654,881, 1 gene, copy number 8: RN7SL594P.
- chr20:31,303,212–64,313,132, 883 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,306. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
